Somatic mutation profile of tumor specimen CDDP-ACIT-TTP1-A (aliquot CDDP-ACIT-TTP1-A-1-0-D-A572-36) from CDDP_EAGLE case CDDP-ACIT, project CDDP_EAGLE-1: CDDP Integrative Analysis of Lung Adenocarcinoma (Phase 2). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 73 years.
Specimen CDDP-ACIT-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 57df9a11-6bf6-4ce2-b493-155e0613492e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen CDDP-ACIT-NB1-A (Blood Derived Normal), aliquot CDDP-ACIT-NB1-A-1-0-D-A572-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b687fe73-d1a8-41df-b392-0e571bcfc1a5

The open-access MAF lists 21 somatic variants for this specimen: 12 protein-altering or splice-affecting, 3 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Silent 3, RNA 3, 5'Flank 2, Nonsense Mutation 1, Intron 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CCNB3 | c.3517-1G>T p.X1173_splice | Splice Site (SNP) | VAF 14/223 reads (6%) | catalogued as COSV52074717; called by muse, mutect2
- KERA | c.576G>T p.K192N | Missense Mutation (SNP) | VAF 14/258 reads (5%) | SIFT tolerated (0.24); PolyPhen benign (0.168); catalogued as COSV99899350; called by muse, mutect2
- KIRREL3 | c.578C>A p.A193D | Missense Mutation (SNP) | VAF 10/126 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.261); catalogued as COSV73109740; called by muse, mutect2
- RYR2 | c.2515G>T p.E839* | Nonsense Mutation (SNP) | VAF 26/470 reads (6%) | catalogued as COSV63660445; called by muse, mutect2
- DYNC2H1 | c.4866A>T p.E1622D | Missense Mutation (SNP) | VAF 20/390 reads (5%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- NLRP4 | c.1215G>T p.E405D | Missense Mutation (SNP) | VAF 16/209 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.875); called by muse, mutect2
- POU6F2 | c.391C>A p.L131I | Missense Mutation (SNP) | VAF 53/514 reads (10%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- PRB1 | c.145G>A p.G49S | Missense Mutation (SNP) | VAF 14/230 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.013); called by muse, mutect2
- PTGER4 | c.256C>A p.P86T | Missense Mutation (SNP) | VAF 11/91 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.557); called by muse, mutect2
- SPATA12 | c.557T>C p.I186T | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0); called by muse, varscan2
- TCHHL1 | c.779C>A p.T260N | Missense Mutation (SNP) | VAF 32/504 reads (6%) | SIFT tolerated (0.43); PolyPhen benign (0.003); called by muse, mutect2
- TNR | c.3447T>A p.S1149R | Missense Mutation (SNP) | VAF 20/304 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- CTNND2 | c.3114C>T p.A1038= | Silent (SNP) | VAF 20/264 reads (8%) | catalogued as rs1561136426; called by muse, mutect2
- LIG3 | c.441A>G p.L147= | Silent (SNP) | VAF 21/334 reads (6%) | called by muse, mutect2
- TTC23L | c.414A>T p.S138= | Silent (SNP) | VAF 15/160 reads (9%) | called by muse, mutect2
- AC024940.1 | n.5139T>A | RNA (SNP) | VAF 24/530 reads (5%) | called by muse, mutect2
- AC083864.1 | n.472T>G | RNA (SNP) | VAF 9/57 reads (16%) | called by muse, mutect2, varscan2
- AC090825.1 | n.493T>C | RNA (SNP) | VAF 14/232 reads (6%) | catalogued as rs1455154263; called by muse, mutect2
- AL353804.7 | chrX:73845589 C>A | 5'Flank (SNP) | VAF 10/112 reads (9%) | called by muse, mutect2
- EGFLAM | c.713-2256G>C | Intron (SNP) | VAF 16/328 reads (5%) | called by muse, mutect2
- MCF2 | chrX:139646875 G>C | 5'Flank (SNP) | VAF 16/147 reads (11%) | catalogued as COSV58482858; called by muse, mutect2, varscan2
